Somatic mutation profile of tumor specimen TCGA-B0-5099-01A (aliquot TCGA-B0-5099-01A-01D-1421-08) from TCGA case TCGA-B0-5099, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 88.6 years (32,364 days).
Specimen TCGA-B0-5099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bbaa46b-76ce-48ef-829b-a610df4b7292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5099-11A (Solid Tissue Normal), aliquot TCGA-B0-5099-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67d6300b-f498-45e1-8970-bc35c765d059

The open-access MAF lists 76 somatic variants for this specimen: 65 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Frame Shift Del 8, Silent 7, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 2, Splice Region 1, Intron 1, 5'UTR 1, 5'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.477del p.E160Sfs*10 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs730882020, CD093920, CM961430, COSV56545604, COSV56548401; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.1980T>A p.S660R | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59383327; called by muse, mutect2, varscan2
- ACO1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59377224; called by muse, mutect2, varscan2
- AHNAK2 | c.7042G>A p.V2348M | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as rs1224121720, COSV60908669; called by muse, mutect2, varscan2
- AP2B1 | c.220A>T p.M74L | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV51997310; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- CCDC88A | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55056950; called by muse, mutect2, varscan2
- CDH4 | c.1710C>A p.D570E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64643082; called by muse, mutect2, varscan2
- CENPF | c.8104C>T p.R2702W | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs376987914; called by muse, mutect2, varscan2
- CEP41 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1364977994, COSV56218579; called by muse, mutect2, varscan2
- CFP | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV55949789; called by muse, mutect2, varscan2
- CLCN4 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66465285; called by muse, mutect2, varscan2
- CRYZ | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV61716998; called by muse, mutect2, varscan2
- DHX37 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58132235; called by muse, mutect2, varscan2
- ECM2 | c.1212T>G p.N404K | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV60739156; called by muse, mutect2, varscan2
- FANCE | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57689169; called by muse, mutect2, varscan2
- GCNT1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 35/278 reads (13%) | catalogued as rs1428067785, COSV65056939; called by muse, mutect2, varscan2
- GOSR1 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 129/325 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.457); catalogued as rs540823264, COSV56718170; called by muse, mutect2, varscan2
- HFM1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022066; called by muse, mutect2
- HSPA8 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 77/247 reads (31%) | catalogued as COSV57082742; called by muse, mutect2
- HSPA8 | c.1037T>A p.I346N | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV57082752; called by muse, mutect2
- IL21 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs141748932; called by muse, mutect2, varscan2
- INTS10 | c.1141-1G>C p.X381_splice | Splice Site (SNP) | VAF 29/108 reads (27%) | catalogued as COSV67603617; called by muse, mutect2, varscan2
- IRF9 | c.1171T>C p.S391P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60702743; called by muse, mutect2, varscan2
- KAT6A | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 110/526 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55903123; called by muse, mutect2, varscan2
- KMT2C | c.7186C>T p.Q2396* | Nonsense Mutation (SNP) | VAF 72/391 reads (18%) | catalogued as rs535169721, COSV51325133; called by muse, mutect2, varscan2
- LGALS8 | c.847A>C p.N283H (on ENST00000341872; = p.N325H on NM_006499.4) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023640; called by muse, mutect2
- MRPS18A | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV64521833; called by muse, mutect2
- NAV3 | c.1656G>T p.E552D | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57063971; called by muse, mutect2, varscan2
- NEO1 | c.3263-1G>A p.X1088_splice | Splice Site (SNP) | VAF 289/838 reads (34%) | catalogued as COSV56067892, COSV99981246; called by muse, mutect2, varscan2
- NPNT | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs768930607, COSV59752102; called by muse, mutect2, varscan2
- P4HA2 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 49/357 reads (14%) | catalogued as COSV51323897; called by muse, mutect2, varscan2
- PCBD2 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV54736637; called by muse, mutect2, varscan2
- PCLO | c.2735T>A p.I912N | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV61617688; called by muse, mutect2
- PLAC8L1 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.503); catalogued as COSV61013608; called by muse, mutect2, varscan2
- PPA2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs142379853; called by muse, mutect2, varscan2
- PPP6R1 | c.1907G>A p.G636E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV69799350; called by muse, mutect2
- RAB9A | c.479A>T p.N160I | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54610552; called by muse, mutect2
- RAPGEF6 | c.4727A>C p.Q1576P | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.379); catalogued as COSV57240885; called by muse, mutect2, varscan2
- RNF20 | c.1992G>T p.M664I | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV66660424; called by muse, mutect2, varscan2
- ROCK1 | c.1659A>T p.L553F | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV67694628; called by muse, mutect2, varscan2
- SCML2 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52618740, COSV99318575; called by muse, mutect2
- SDK2 | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV66181893; called by muse, mutect2
- SECISBP2L | c.2884G>A p.G962S (on ENST00000559471 / NM_001193489.2; = p.G917S on NM_014701.4) | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55932931; called by muse, mutect2, varscan2
- SFMBT1 | c.1106C>G p.A369G | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV56252130; called by muse, varscan2
- SFMBT1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56252154; called by muse, varscan2
- SLC15A3 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV50001582; called by muse, mutect2, varscan2
- TAF1L | c.4735C>A p.H1579N | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV54258453; called by muse, mutect2, varscan2
- TAF1L | c.4734G>C p.K1578N | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.553); catalogued as COSV54258482, COSV54272080; called by muse, mutect2, varscan2
- THBS1 | c.2253G>T p.R751S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.828); catalogued as COSV52950285; called by muse, mutect2
- UBXN6 | c.875T>G p.F292C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56670511; called by muse, mutect2, varscan2
- USP26 | c.1978T>C p.Y660H | Missense Mutation (SNP) | VAF 124/322 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV63708119; called by muse, mutect2, varscan2
- VANGL2 | c.192G>C p.R64= | Splice Region (SNP) | VAF 33/105 reads (31%) | catalogued as COSV63604055; called by muse, mutect2, varscan2
- YTHDC1 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.99); catalogued as COSV60008866; called by muse, mutect2, varscan2
- CNOT1 | c.5048_5052del p.R1683Qfs*32 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | called by mutect2, pindel, varscan2
- DCTN1 | c.3647del p.G1216Efs*33 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel
- DHRS13 | c.441del p.L148Cfs*2 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- GPR180 | c.725_727del p.S242_L243delinsM | In Frame Del (DEL) | VAF 50/158 reads (32%) | called by mutect2, pindel, varscan2
- GRM1 | c.670_671insA p.W224* | Nonsense Mutation (INS) | VAF 62/226 reads (27%) | called by mutect2, pindel, varscan2
- HSP90AB1 | c.1446dup p.I483Hfs*7 | Frame Shift Ins (INS) | VAF 83/310 reads (27%) | called by mutect2, pindel, varscan2
- IGF2R | c.7386del p.K2463Sfs*10 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel
- NFAM1 | c.318dup p.N107Efs*131 | Frame Shift Ins (INS) | VAF 99/240 reads (41%) | called by mutect2, pindel, varscan2
- PURG | c.341_348del p.E114Gfs*65 | Frame Shift Del (DEL) | VAF 37/155 reads (24%) | called by mutect2, pindel, varscan2
- RAD54L | c.464del p.P155Lfs*7 | Frame Shift Del (DEL) | VAF 55/184 reads (30%) | called by mutect2, pindel, varscan2
- SCN9A | c.4594del p.M1532* (on ENST00000303354; = p.M1521* on NM_002977.3) | Frame Shift Del (DEL) | VAF 47/204 reads (23%) | called by mutect2, pindel, varscan2
- CADM3 | c.123G>A p.V41= (on ENST00000368125 / NM_001127173.3; = p.V75= on NM_021189.5) | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV63684081; called by muse, mutect2, varscan2
- ERCC6 | c.2089T>C p.L697= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as COSV63388113; called by muse, mutect2, varscan2
- HPN | c.45A>G p.R15= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as rs759965464, COSV52882328; called by muse, mutect2, varscan2
- RAI14 | c.78C>G p.A26= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV54289960; called by muse, mutect2, varscan2
- SASS6 | c.714T>C p.D238= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as COSV54926609; called by muse, mutect2, varscan2
- SECISBP2L | c.2883T>G p.T961= (on ENST00000559471 / NM_001193489.2; = p.T916= on NM_014701.4) | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as COSV55932950; called by muse, mutect2, varscan2
- TOM1L2 | c.1062C>A p.L354= (on ENST00000379504 / NM_001350333.2; = p.L304= on NM_001033551.3) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV58884365; called by muse, mutect2
- AC024940.1 | n.4917T>G | RNA (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503155 C>T | 5'Flank (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CCDC112 | c.-36C>T | 5'UTR (SNP) | VAF 40/139 reads (29%) | catalogued as rs187304678, COSV65472709; called by muse, mutect2, varscan2
- ZBED3 | c.-152-1835T>C | Intron (SNP) | VAF 8/91 reads (9%) | catalogued as COSV54896907; called by muse, mutect2
